Somatic mutation profile of tumor specimen TCGA-AR-A1AP-01A (aliquot TCGA-AR-A1AP-01A-11D-A12Q-09) from TCGA case TCGA-AR-A1AP, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 80.5 years (29,406 days).
Specimen TCGA-AR-A1AP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e09b589-1395-4a71-9842-de4bbf4ea83c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A1AP-10A (Blood Derived Normal), aliquot TCGA-AR-A1AP-10A-01D-A12Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48b0da3c-8c02-4e12-8dd4-1ddb742b2d8b

The open-access MAF lists 31 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 4, Splice Site 2, 3'UTR 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 198/299 reads (66%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRG7 | c.1964A>G p.N655S | Missense Mutation (SNP) | VAF 123/313 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV56294080, COSV56294809; called by muse, mutect2, varscan2
- ARMH4 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 135/270 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs1181281069, COSV50761965; called by muse, mutect2, varscan2
- CAPN5 | c.1149C>G p.I383M (on ENST00000456580; = p.I343M on NM_004055.5) | Missense Mutation (SNP) | VAF 35/376 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.102); catalogued as COSV99582603; called by muse, mutect2
- CFAP61 | c.1345G>A p.E449K | Missense Mutation (SNP) | VAF 111/238 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0.09); catalogued as rs763745319, COSV55620863; called by muse, mutect2, varscan2
- COL4A1 | c.3307G>A p.G1103R | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM128683, COSV65422174; called by muse, mutect2, varscan2
- DHX58 | c.1322C>T p.A441V | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as rs553858409, COSV52424787; called by muse, mutect2, varscan2
- DZIP3 | c.358C>G p.Q120E | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV64311266; called by muse, mutect2, varscan2
- ELAPOR2 | c.2521C>T p.P841S (on ENST00000450689 / NM_001142749.3; = p.P674S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/248 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51884556; called by muse, mutect2, varscan2
- GATA3 | c.922-3_922-2del p.X308_splice | Splice Site (DEL) | VAF 51/238 reads (21%) | catalogued as rs763236375, COSV60515023; called by mutect2, pindel, varscan2
- GLYCTK | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1037371018, COSV59793136; called by muse, mutect2, varscan2
- MAP4K1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.011); catalogued as rs759106165, COSV67708824; called by muse, mutect2, varscan2
- MMP14 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1209497673, COSV61287648; called by muse, mutect2, varscan2
- MPO | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.502); catalogued as COSV56561706; called by muse, mutect2, varscan2
- PDZD7 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs768381051, COSV64645534; called by muse, mutect2, varscan2
- PRB2 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 172/554 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.763); catalogued as COSV66982018; called by muse, mutect2, varscan2
- SAT1 | c.442C>A p.L148M | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63380624; called by muse, mutect2, varscan2
- SLFN11 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 239/452 reads (53%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs1229291682, COSV57697698; called by muse, varscan2
- SNX25 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV53012029; called by muse, mutect2, varscan2
- STX19 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 81/236 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV57396512; called by muse, mutect2, varscan2
- TENM3 | c.5765C>T p.A1922V | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV69300181; called by muse, mutect2, varscan2
- TGFBR2 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM095010, COSV55444526, COSV55453983; called by muse, mutect2, varscan2
- TOX2 | c.749A>T p.K250M (on ENST00000358131 / NM_001098798.2; = p.K199M on NM_032883.3) | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57883089; called by muse, mutect2, varscan2
- ZNF667 | c.350A>T p.K117I | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.769); catalogued as COSV99410996; called by muse, mutect2
- STRA6 | c.113+1G>T p.X38_splice | Splice Site (SNP) | VAF 29/83 reads (35%) | called by muse, mutect2, varscan2
- MET | c.1170C>T p.Y390= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as rs45552236, COSV59258790; ClinVar: likely benign; called by muse, mutect2
- NOX3 | c.570G>A p.S190= | Silent (SNP) | VAF 51/149 reads (34%) | catalogued as rs143177002; called by muse, mutect2, varscan2
- TMPPE | c.606C>G p.A202= | Silent (SNP) | VAF 32/192 reads (17%) | catalogued as COSV56561694; called by muse, mutect2, varscan2
- URI1 | c.1464A>G p.S488= | Silent (SNP) | VAF 50/150 reads (33%) | catalogued as COSV56348292; called by muse, mutect2, varscan2
- ANKRD13D | c.*813G>A | 3'UTR (SNP) | VAF 97/273 reads (36%) | catalogued as rs750361664, COSV57383562; called by muse, mutect2, varscan2
- DDIT3 | c.-81+1177C>G | Intron (SNP) | VAF 62/181 reads (34%) | catalogued as COSV56252809; called by muse, mutect2, varscan2
